Somatic mutation profile of tumor specimen MP2PRT-PASFWB-TBP1-A (aliquot MP2PRT-PASFWB-TBP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASFWB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,437 days).
Specimen MP2PRT-PASFWB-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf259b74-b2e5-4ba6-83f2-a27fd44f7b87.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASFWB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASFWB-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fdf6fa5-1a18-47ed-8fb9-3394f5a47e50

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLPTM1L | c.1595C>T p.T532M | Missense Mutation (SNP) | VAF 23/480 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs770025461, COSV57989090; called by muse, mutect2
- CREBBP | c.4447A>T p.I1483F | Missense Mutation (SNP) | VAF 79/366 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52117349; called by muse, varscan2
- LRATD1 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 100/512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1266372200; called by muse, mutect2, varscan2
- OR1P1 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925646905; called by muse, mutect2, varscan2
- RARB | c.338G>A p.R113H (on ENST00000383772 / NM_001290216.2; = p.R106H on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1163604076; called by muse, mutect2, varscan2
- RIPOR2 | c.2492C>T p.A831V | Missense Mutation (SNP) | VAF 87/491 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs1252786981; called by muse, mutect2, varscan2
- RTN1 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 34/788 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as rs867180903, COSV99954276; called by muse, mutect2
- ST14 | c.2371G>A p.V791M | Missense Mutation (SNP) | VAF 95/437 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1470712732, COSV53832857; called by muse, mutect2, varscan2
- THSD4 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 178/602 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1197511713; called by muse, varscan2
- TMEM132B | c.641C>T p.T214M | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs370220788, COSV54762341; called by muse, mutect2, varscan2
- ADAMTS13 | c.555G>T p.L185F | Missense Mutation (SNP) | VAF 33/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSF2 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PHC1 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 74/459 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PIKFYVE | c.3608G>A p.W1203* | Nonsense Mutation (SNP) | VAF 56/195 reads (29%) | called by muse, mutect2, varscan2
- NDUFB10 | c.6G>A p.P2= | Silent (SNP) | VAF 65/267 reads (24%) | called by muse, mutect2, varscan2
- RBMXL2 | c.969C>T p.R323= | Silent (SNP) | VAF 139/427 reads (33%) | catalogued as rs772833571, COSV60981408; called by muse, mutect2, varscan2
- RNF152 | c.477C>T p.G159= | Silent (SNP) | VAF 178/468 reads (38%) | catalogued as rs954973068; called by muse, mutect2, varscan2
- SPANXD | c.234C>T p.N78= | Silent (SNP) | VAF 21/692 reads (3%) | catalogued as COSV100982271, COSV65152551; called by muse, mutect2
- MROH2A | c.3866+14C>T | Intron (SNP) | VAF 15/238 reads (6%) | catalogued as rs952950609; called by muse, mutect2
